Somatic mutation profile of tumor specimen MBCProject_1471_T1_WES (aliquot MBCProject_1471_T1_WES_1) from CMI case MBCProject_1471, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.5 years (14,078 days).
Specimen MBCProject_1471_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35fba273-fc68-4f74-a695-6177a52272ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1471_SALIVA (Saliva), aliquot MBCProject_1471_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79cf1600-eb13-43fb-b354-1e4b0d380432

The open-access MAF lists 61 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Intron 7, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.533G>C p.W178S | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV99190903; called by muse, varscan2
- ADAM11 | c.2035G>A p.G679S | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.762); catalogued as rs754922345, COSV52347126, COSV52349801; called by muse, mutect2, varscan2
- ANKRD34C | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1012642552; called by muse, mutect2, varscan2
- ANKS1B | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs757376360, COSV61362600; called by muse, varscan2
- ASAP1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1405718044; called by muse, mutect2
- ASTN2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.727); catalogued as rs554132287, COSV57804953; called by muse, mutect2
- ATP9B | c.2032G>A p.G678R | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs138778143; called by muse, mutect2, varscan2
- CILK1 | c.1598G>A p.G533E (on ENST00000350082 / NM_001375397.1; = p.G526E on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs758717575; called by muse, mutect2, varscan2
- COL11A2 | c.4675C>T p.R1559W (on ENST00000341947 / NM_080680.3; = p.R1452W on NM_080679.2) | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as rs370966667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCR3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs778747458; called by muse, mutect2, varscan2
- EGFR | c.2095C>A p.P699T | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV51815916; called by muse, mutect2
- FAM133A | c.538dup p.R180Kfs*7 | Frame Shift Ins (INS) | VAF 9/61 reads (15%) | catalogued as rs1273788336; called by mutect2, varscan2
- INPP5D | c.1899C>T p.F633= (on ENST00000445964 / NM_001017915.3; = p.F632= on NM_005541.5) | Splice Region (SNP) | VAF 15/96 reads (16%) | catalogued as rs375044485; called by muse, mutect2, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by mutect2, varscan2
- LARP1B | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1457959954; called by muse, varscan2
- NEK4 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1169698033; called by muse, mutect2
- RNF183 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs779635734; called by muse, mutect2, varscan2
- ATP2B1 | c.2779A>G p.T927A | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- BSN | c.11364G>T p.Q3788H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CABCOCO1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, varscan2
- CLDN5 | c.539T>C p.L180P (on ENST00000618236 / NM_001363066.2; = p.L265P on NM_003277.4) | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CYP11B1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DNAH8 | c.12291T>A p.D4097E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- DSC3 | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- IGLV5-45 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- KLF4 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- L1CAM | c.3364T>G p.W1122G | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LEMD3 | c.1691T>C p.L564S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NUDCD3 | c.862A>C p.I288L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PCNX2 | c.3401G>T p.G1134V | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- PDZD4 | c.1523del p.G508Afs*47 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- PPP2R5B | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SLAIN1 | c.1189G>T p.G397* (on ENST00000466548; = p.G134* on NM_144595.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2
- SLC6A8 | c.1014C>A p.Y338* | Nonsense Mutation (SNP) | VAF 117/391 reads (30%) | called by muse, mutect2, varscan2
- STRIP2 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.151); called by muse, mutect2
- VBP1 | c.468T>G p.D156E | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- VGLL1 | c.647_648del p.Y216Cfs*13 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by pindel, varscan2
- WDR33 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ANKFN1 | c.3282C>T p.D1094= (on ENST00000653862; = p.D947= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/651 reads (5%) | catalogued as rs996720759; called by muse, mutect2
- CCN4 | c.189G>A p.P63= | Silent (SNP) | VAF 26/364 reads (7%) | catalogued as rs1236323552, COSV51535426; called by muse, mutect2
- CYB561 | c.186C>T p.I62= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as COSV62539817; called by muse, mutect2, varscan2
- DCLK1 | c.165G>A p.K55= | Silent (SNP) | VAF 49/325 reads (15%) | catalogued as COSV55175683; called by muse, mutect2, varscan2
- DOCK2 | c.1359C>T p.C453= | Silent (SNP) | VAF 28/175 reads (16%) | catalogued as rs753193611, COSV56940595, COSV56971881; called by muse, mutect2, varscan2
- GFAP | c.1191C>T p.D397= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs1297179058, COSV99492949; called by muse, mutect2, varscan2
- GRK1 | c.1260C>T p.S420= | Silent (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- GSTM4 | c.630A>C p.T210= | Silent (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2, varscan2
- LTBP2 | c.4494G>A p.P1498= | Silent (SNP) | VAF 48/345 reads (14%) | catalogued as rs756171656, COSV56210503; called by muse, mutect2, varscan2
- MYO18B | c.1833C>T p.L611= | Silent (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1830G>A p.T610= | Silent (SNP) | VAF 45/207 reads (22%) | catalogued as COSV53370223; called by muse, mutect2, varscan2
- PCDHB8 | c.1833G>A p.T611= | Silent (SNP) | VAF 34/631 reads (5%) | catalogued as rs563679514, COSV99177289; called by muse, mutect2
- PLXNA1 | c.2961C>T p.N987= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs767692996; called by muse, mutect2, varscan2
- RAB9B | c.81C>T p.Y27= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as rs141822799, COSV54587221; called by muse, mutect2
- RBMXL3 | c.765G>C p.A255= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- UBAP2L | c.9A>G p.T3= | Silent (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- ABLIM1 | c.1041+2625T>C | Intron (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- ABRAXAS1 | c.178+1805C>T | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- ETFB | c.58-346T>A | Intron (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- EYS | c.1767-8533C>T | Intron (SNP) | VAF 20/522 reads (4%) | called by muse, mutect2
- KCNK1 | c.356-16594T>G | Intron (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- RPSA | c.252+11C>T | Intron (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- WDR87 | c.129+84C>T | Intron (SNP) | VAF 10/169 reads (6%) | called by muse, mutect2
